Gene-level copy-number profile of tumor specimen TCGA-XR-A8TD-01A from TCGA case TCGA-XR-A8TD, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, clear cell type; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 49.0 years (17,908 days).
Specimen TCGA-XR-A8TD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.f4219201-e72a-411a-8e1f-3a067fdf8e67.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XR-A8TD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0511cb90-719b-4c64-a28b-69b94279b905

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 7,661; copy number 2: 44,004; copy number 3: 7,635; copy number 4: 490; copy number 5: 1; copy number 6: 8; copy number 7: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XR-A8TD-01A-12D-A38W-01): tumor purity 0.45, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:98,288,109–98,708,935, 2 genes (within-gene range 0–1): GABBR2, SEPTIN7P7.
- chr10:88,876,450–89,139,458, 11 genes: PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:194,827,890–194,832,592, 1 gene, copy number 5: AC090505.2.
- chr6:79,854,684–80,042,527, 8 genes, copy number 6: AL132875.1, AL132875.3, AL132875.2, ELOVL4, AL133475.1, GAPDHP63, RPL35AP18, TTK.
- chr6:167,111,807–167,196,913, 6 genes, copy number 7: CCR6, AL121935.1, AL121935.2, TCP10L2, GPR31, AL121935.3.

Autosomal genes at a single copy (total copy number 1): 7,661. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
